Gene-level copy-number profile of tumor specimen TCGA-AC-A3W5-01A from TCGA case TCGA-AC-A3W5, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.8 years (24,029 days).
Specimen TCGA-AC-A3W5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.28b8f0a3-764b-4156-aea9-dc97f06fac1f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A3W5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e8a263d7-4230-4bec-92ab-8b80be0000fc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,994; copy number 2: 12,284; copy number 3: 17,610; copy number 4: 20,961; copy number 5: 2,383; copy number 6: 2,395; copy number 7: 2,096; copy number 8: 6; copy number 12: 56; copy number 14: 1; copy number 44: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A3W5-01A-11D-A227-01): tumor purity 0.48, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 80 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:39,461,486–40,999,906, 80 genes, copy number 12–44 (within-gene range 4–44) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,922. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
